Surgical pathology report (de-identified scan), TCGA case TCGA-RE-A7BO, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RE-A7BO-01A (Primary Tumor).

[page 1 of 2]
FILE IN PATIENT HISTORY

Patient Location

Name

Given Name

DOB

Patient Address

Consultant

Sex

Tel:

HISTOLOGY

FILE IN PATIENT HISTORY

Cell
Path Adenocarcinoma NOS 8/40/13
Adenocarcinoma, mucinous NOS 8/480/13
Site: Distal third oesophagus C15.5
9/1 9/15/13

HISTOPATHOLOGY REPORT

Received
Lab No
Collected

CLINICAL NOTES

oesophagectomy. Adenocarcinoma distal oesophagus.

MACROSCOPY

1. Labelled: Oesophagus, gastrectomy.

The specimen is an oesophago-gastrectomy consisting of oesophagus measuring 40 mm in length and 25 mm in diameter with attached proximal stomach, 30 mm along the lesser curve, 90 mm along the greater curve with an L-shaped resection margin measuring 100 x 40 mm, peri-oesophageal fat up to 5 mm thick, lesser omentum and greater omentum. At the oesophago-gastric junction is an ovoid polypoid tumour 55 x 20 x 20 mm. The tumour is 20 mm from the proximal and 50 mm from the distal margin. On slicing the tumour infiltrates into submucosa only, without penetrating the muscularis propria. The adjacent oesophageal mucosa shows an irregular area of tan velvety mucosa consistent with Barrett's mucosa. The stomach mucosa is unremarkable. Within the peri-oesophageal tissue/omentum there are a moderate number of lymph nodes up to 12 mm which show grey tumour tissue on slicing.

1.1-2 Proximal margin perpendicular, 1.3-6 tumour, 1.7 adjacent Barrett's, 1.8 distal margin, 1.9 proximal stomach, 1.10-11 lesser omental nodes, 1.10 (5), 1.11 (1), 1.12-14 greater omental nodes, 1.12 (6), 1.13 (6), 1.14 (5, 1 bisected marked blue). P14

2. Labelled: Gall bladder.

An unopened gallbladder measuring 130 mm in length and 50 mm in diameter. In the lumen are multiple granular black calculi up to 6 mm in diameter. The mucosa is unremarkable. The gall bladder wall is 1-2 mm thick. The serosa is smooth and shiny. P1 SM

MICROSCOPY

1. Sections from the tumour show it to be a poorly differentiated adenocarcinoma with mucinous differentiation arising within a field of Barrett's mucosa. The tumour is partly exophytic and papillary but partly composed of irregularly sized and shaped glands, cords and clusters of cells which float within pools of mucin. The tumour cells have pleomorphic hyperchromatic nuclei, prominent nucleoli and moderate amounts of cytoplasm. There are moderate numbers of mitoses. The tumour has a lobular border and extends into the submucosa extending close to but not invading the muscularis propria. Definite lymphovascular invasion is not identified. Perineural invasion is not identified. There is a surrounding mixed inflammatory cell infiltrate. Adenocarcinoma is clear of the proximal and distal resection margins. The adjacent oesophageal mucosa shows Barrett's metaplasia of specialised (intestinal) type, with extensive intestinal metaplasia and low and

ANATOMICAL PATH

	Please discard any previous ANATOMICAL PATH HISTOLOGY report of the same page number printed before	Page 1 of 2 Report

[page 2 of 2]
FILE IN PATIENT HISTORY

Patient Location

Name

Given Name

DOB

Patient Address

Consultant

Sex

Tel:

HISTOLOGY

FILE IN PATIENT HISTORY

HISTOPATHOLOGY REPORT

Received

Lab No

Collected

high-grade dysplasia. Low-grade dysplasia extends to the proximal resection margin. The stomach shows a minimal chronic gastritis. Helicobacter are not seen.

6 lymph nodes were identified in the lesser omentum 2 of which show metastatic adenocarcinoma, one with a focus of extra-nodal spread 17 mm in maximum dimension. 16 lymph nodes were identified in the greater omentum, which show no evidence of malignancy.

2. Sections consist of a gall bladder showing mild chronic cholecystitis. There is no evidence of malignancy.

DIAGNOSIS

1. Oesophagogastrrectomy:

a) Poorly differentiated mucinous adenocarcinoma of distal oesophagus, 55mm in maximum dimension, infiltrating to the depth of the submucosa, clear of resection margins, with metastases to 2 of 6 lesser omental lymph nodes, with focal extra-nodal spread up to 17 mm, no metastases in a further 16 greater omental lymph nodes,

b) Barrett's mucosa of specialised (intestinal) type, with low and high-grade dysplasia, low-grade dysplasia extending to oesophageal resection margin,

c) Proximal stomach showing mild inactive chronic gastritis.

2. Gall bladder: Mild chronic cholecystitis.

ANATOMICAL PATH

	Please discard any previous ANATOMICAL PATH HISTOLOGY report of the same page number printed before	Page 2 of 2 Report

Source: NCI Genomic Data Commons file 5e393b05-a0cb-45c2-acb8-5eeeb32d3efd (TCGA-RE-A7BO.F93A9493-DDAB-4A45-BD57-2FE1D0FC83F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).